Gene-level copy-number profile of tumor specimen TCGA-02-0099-01A from TCGA case TCGA-02-0099, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 46.8 years (17,080 days).
Specimen TCGA-02-0099-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.f26408e6-2880-47d7-9dae-6d2d481c1ea0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-02-0099-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/786d0def-dfc1-44e0-aa88-a3f122581074

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,327; copy number 2: 42,105; copy number 3: 4,271; copy number 12: 2; copy number 13: 22; copy number 19: 9; copy number 22: 16; copy number 23: 20; copy number 26: 3; copy number 27: 1; copy number 28: 7; copy number 29: 21; copy number 33: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0099-01): tumor purity 0.72, ploidy 1.87, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 112 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:57,253,762–57,431,005, 2 genes, copy number 22 (within-gene range 1–22): R3HDM2, RNU6-879P.
- chr12:57,459,785–57,547,224, 9 genes, copy number 19: GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2.
- chr12:57,674,665–57,959,148, 25 genes, copy number 13–26: RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG.
- chr12:61,708,259–62,417,431, 10 genes, copy number 29 (within-gene range 2–29): TAFA2, RPL21P104, KRT8P19, RPS3P6, AC078789.1, KLF17P1, USP15, MIR6125, RNU6-595P, Metazoa_SRP.
- chr12:62,482,349–62,484,932, 1 gene, copy number 29: AC079035.1.
- chr12:62,643,994–62,935,150, 1 gene, copy number 33 (within-gene range 3–33): PPM1H.
- chr12:62,755,227–63,154,006, 10 genes, copy number 33: GAPDHP44, RNU1-83P, Y_RNA, RPL14P1, AC078814.2, LDHAL6CP, AC078814.1, RSL24D1P5, AVPR1A, AC135584.1.
- chr12:63,292,625–63,668,939, 2 genes, copy number 12 (within-gene range 1–12): AC026116.1, DPY19L2.
- chr12:63,887,379–63,888,598, 1 gene, copy number 27: AC079866.1.
- chr12:64,038,562–64,222,296, 6 genes, copy number 29 (within-gene range 1–29): AC020611.2, AC025576.3, AC025576.2, AC025576.1, C12orf66, RNU6-1009P.
- chr12:64,228,560–64,228,675, 1 gene, copy number 29: RNU5A-7P.
- chr12:64,266,413–64,266,766, 1 gene, copy number 29: OOEPP2.
- chr12:64,507,001–64,697,564, 1 gene, copy number 22 (within-gene range 2–22): RASSF3.
- chr12:64,575,665–64,977,509, 13 genes, copy number 22 (within-gene range 2–22): SNORD83, AC078962.4, MIR548C, MIR548Z, AC078962.1, AC078962.3, AC025262.2, AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39.
- chr12:67,929,235–68,234,686, 7 genes, copy number 28 (within-gene range 1–28): LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG.
- chr12:68,552,995–68,971,570, 20 genes, copy number 23 (within-gene range 1–23): RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:69,585,426–69,610,907, 2 genes, copy number 29 (within-gene range 1–29): CCT2, LRRC10.

Autosomal genes at a single copy (total copy number 1): 10,947. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
